Somatic mutation profile of tumor specimen 0DI8ME from CCDI case PBBUXI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelial-myoepithelial carcinoma; Tissue or organ of origin: Parotid gland; Age at diagnosis: 14.1 years (5,156 days).
Specimen 0DI8ME: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c860268-5ac2-410c-bca7-92db331d16fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI8M9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eb23e5b-85c6-4a49-ba0d-b18bde8b60cf

The open-access MAF lists 686 somatic variants for this specimen: 353 protein-altering or splice-affecting, 204 silent, 129 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 325, Silent 204, Intron 71, 3'UTR 19, 5'UTR 18, Nonsense Mutation 17, RNA 9, 3'Flank 7, Splice Region 7, 5'Flank 5, Splice Site 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 324/580 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 263/620 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 199/566 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868238523, COSV62337400, COSV62339851, COSV62344458; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.6589G>A p.E2197K | Missense Mutation (SNP) | VAF 238/553 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs751604379, COSV100718660; called by muse, mutect2, varscan2
- ACSM5 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59372849; called by muse, mutect2, varscan2
- ADGRE3 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 85/267 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53728527; called by muse, mutect2, varscan2
- AL121899.2 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 210/382 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198386; called by muse, mutect2, varscan2
- ALB | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 144/382 reads (38%) | catalogued as rs75470261, CM940019; ClinVar: not provided; called by muse, mutect2, varscan2
- ALOX15B | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 243/584 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as COSV66479562; called by muse, mutect2, varscan2
- ANKRD30A | c.3379G>A p.E1127K (on ENST00000611781; = p.E1071K on NM_052997.2) | Missense Mutation (SNP) | VAF 176/409 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV64616667; called by muse, varscan2
- ANKRD30A | c.3385G>A p.E1129K (on ENST00000611781; = p.E1073K on NM_052997.2) | Missense Mutation (SNP) | VAF 153/418 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV64607971; called by muse, varscan2
- ANKRD35 | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 200/460 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs782375317, COSV62911965; called by muse, mutect2, varscan2
- AR | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 176/216 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65956508; called by muse, mutect2, varscan2
- ATP8B3 | c.3881C>T p.S1294L | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs764922106, COSV59543438, COSV59546748; called by muse, mutect2, varscan2
- BSN | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 261/628 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99609624; called by muse, mutect2, varscan2
- CASP10 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 131/387 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as rs752039240; called by muse, mutect2, varscan2
- CCDC136 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 521/893 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs987941411, COSV52801677; called by muse, mutect2, varscan2
- CD163L1 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 135/361 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV58011090; called by muse, mutect2, varscan2
- CD1E | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 238/570 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs868718790, COSV63769843; called by muse, mutect2, varscan2
- CD38 | c.403T>C p.F135L | Missense Mutation (SNP) | VAF 174/482 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56888301; called by muse, mutect2, varscan2
- CDHR3 | c.1430G>A p.R477K | Missense Mutation (SNP) | VAF 140/476 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.096); catalogued as rs549791594; called by muse, varscan2
- CEP126 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 165/485 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV54821986; called by muse, mutect2, varscan2
- CHRNA4 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 390/690 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64721299; called by muse, mutect2, varscan2
- COL2A1 | c.4405G>A p.D1469N | Missense Mutation (SNP) | VAF 206/521 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM050202, CM1513363; called by muse, mutect2, varscan2
- COL4A6 | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 218/263 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777747305, COSV57874835; called by muse, mutect2, varscan2
- COL4A6 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 114/149 reads (77%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs759981449, COSV100565023; called by muse, mutect2, varscan2
- COL5A1 | c.2287-1G>A p.X763_splice | Splice Site (SNP) | VAF 110/305 reads (36%) | catalogued as COSV100879663; called by muse, mutect2, varscan2
- COL6A6 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 164/419 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0.062); catalogued as rs1421121378; called by muse, mutect2, varscan2
- COLGALT2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 381/1085 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747007291, COSV62300222; called by muse, mutect2, varscan2
- COPS5 | c.921-4C>T | Splice Region (SNP) | VAF 182/306 reads (59%) | catalogued as COSV100769936; called by mutect2, varscan2
- CRB1 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 362/744 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs757279881, HM060031, COSV66328646; called by muse, mutect2, varscan2
- CROCC2 | c.3698G>A p.R1233Q | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as rs868619658; called by muse, mutect2
- CSMD1 | c.9572C>T p.S3191F (on ENST00000520002; = p.S3190F on NM_033225.6) | Missense Mutation (SNP) | VAF 207/996 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59322410; called by muse, mutect2
- CSMD1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 188/767 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1222649079, COSV68195980; called by muse, mutect2, varscan2
- CSTA | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs770962641, COSV52612781; called by muse, varscan2
- CT45A3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 110/1532 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.092); catalogued as rs1191086988; called by muse, mutect2
- CTC1 | c.3488G>A p.R1163K | Missense Mutation (SNP) | VAF 271/596 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV59853580; called by muse, mutect2, varscan2
- DNAH3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 206/481 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs760379497, COSV54529137; called by muse, mutect2, varscan2
- DNAH8 | c.4108G>A p.G1370R | Missense Mutation (SNP) | VAF 349/634 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs939877826; called by muse, mutect2, varscan2
- DNAJC10 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 178/475 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs371494397; called by muse, mutect2, varscan2
- DSC2 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 245/535 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369761766; called by muse, mutect2, varscan2
- DSCAM | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 166/490 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs766432150, COSV68021124; called by muse, mutect2, varscan2
- EPHA3 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 299/666 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60726302; called by muse, mutect2, varscan2
- ERAP2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 159/413 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV65938668; called by muse, mutect2, varscan2
- FGF16 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 184/225 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs781914307, COSV71546153; called by muse, mutect2, varscan2
- FKBP1A | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 179/684 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101098379, COSV67750534; called by muse, mutect2, varscan2
- FRRS1L | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 161/437 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101643898; called by muse, mutect2, varscan2
- FRYL | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 139/406 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.189); catalogued as rs776621707; called by muse, mutect2, varscan2
- FSCN3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 171/562 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50001694; called by muse, mutect2, varscan2
- FSHR | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 176/448 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100437362; called by muse, mutect2, varscan2
- GABRA1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.992); catalogued as rs773012684; called by muse, mutect2, varscan2
- GAL3ST2 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 146/360 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1193409190, COSV99510974; called by muse, mutect2, varscan2
- GALNT7 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 175/465 reads (38%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.519); catalogued as COSV53931402; called by muse, mutect2, varscan2
- GLB1L2 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV60278524; called by muse, mutect2, varscan2
- GLIPR1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 217/557 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574219796, COSV56990729; called by muse, mutect2, varscan2
- GPR179 | c.889G>A p.D297N (on ENST00000621958; = p.D296N on NM_001004334.4) | Missense Mutation (SNP) | VAF 132/288 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs867593960; called by muse, mutect2, varscan2
- GPR84 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 135/349 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.371); catalogued as rs1033818588; called by muse, mutect2, varscan2
- GRHL2 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 676/1018 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs923030287, COSV52548731, COSV99307988; called by muse, varscan2
- GRIN2A | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 200/509 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs267604688, COSV58032774; called by muse, mutect2, varscan2
- GRM5 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 144/392 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59599864; called by muse, mutect2, varscan2
- GRM8 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 439/804 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs559451048; called by muse, mutect2, varscan2
- GSTM3 | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 389/488 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1461789088; called by muse, mutect2, varscan2
- HIPK2 | c.3031G>A p.G1011S | Missense Mutation (SNP) | VAF 239/802 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1480935968, COSV101301612, COSV69210173; called by muse, mutect2, varscan2
- HPF1 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 205/500 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs781328588; called by muse, mutect2, varscan2
- HS3ST4 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 104/297 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV58806132; called by muse, mutect2, varscan2
- HYOU1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 180/458 reads (39%) | catalogued as rs781850918, COSV101345706; called by muse, varscan2
- IGFN1 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 229/463 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1423160961, COSV55186868; called by muse, mutect2, varscan2
- IL11 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 142/409 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52773968; called by muse, mutect2
- KIF9 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 147/374 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773610436, COSV55520707, COSV55524288; called by muse, mutect2, varscan2
- KRT14 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 180/487 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1215846581; called by muse, mutect2, varscan2
- KRTAP5-3 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 110/361 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV101294504; called by muse, mutect2, varscan2
- KRTAP5-4 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 112/262 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1298802172, COSV68788813; called by muse, mutect2, varscan2
- LAD1 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 284/665 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100943800; called by muse, mutect2, varscan2
- LAMB3 | c.2273G>A p.G758E | Missense Mutation (SNP) | VAF 294/737 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1425608024; called by muse, mutect2, varscan2
- LAMB3 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 256/603 reads (42%) | catalogued as rs1467836602, COSV100620004; called by muse, mutect2, varscan2
- LCE1C | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 444/972 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs769794819, COSV64218694; called by muse, mutect2, varscan2
- LGALS13 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 214/552 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.231); catalogued as COSV55680590; called by muse, mutect2, varscan2
- LILRA1 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 206/553 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as rs1234761456; called by muse, mutect2, varscan2
- LILRB1 | c.638C>T p.S213L (on ENST00000427581; = p.S177L on NM_006669.6) | Missense Mutation (SNP) | VAF 153/364 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs760073992, COSV61121914; called by muse, mutect2, varscan2
- LILRB2 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 160/413 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as rs1458436430, COSV58748023; called by muse, varscan2
- LRRCC1 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 377/607 reads (62%) | catalogued as COSV100835382; called by muse, mutect2, varscan2
- MAGEA3 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 381/466 reads (82%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as rs1556826582, COSV64755846; called by muse, mutect2, varscan2
- MAST4 | c.1582C>T p.P528S (on ENST00000403625 / NM_001164664.2; = p.P339S on NM_015183.3) | Missense Mutation (SNP) | VAF 181/391 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55114065; called by muse, mutect2, varscan2
- MERTK | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 131/316 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162296660; called by muse, mutect2, varscan2
- MFSD6L | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 173/429 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1266934070, COSV61002360; called by muse, mutect2, varscan2
- MNDA | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 255/624 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63740234; called by muse, mutect2, varscan2
- MT1X | c.43T>C p.C15R | Missense Mutation (SNP) | VAF 189/499 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs776781176; called by muse, mutect2, varscan2
- MUC16 | c.17552C>T p.P5851L | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV101200752, COSV67494343; called by muse, mutect2, varscan2
- MUC16 | c.5281G>A p.E1761K | Missense Mutation (SNP) | VAF 112/326 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV67463987; called by muse, mutect2, varscan2
- MUC16 | c.3427C>T p.P1143S | Missense Mutation (SNP) | VAF 173/456 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.116); catalogued as COSV67461668, COSV67480114; called by muse, mutect2, varscan2
- MYH2 | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 350/911 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs763292061, COSV55432650; called by muse, mutect2, varscan2
- NETO1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 158/403 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV55001912, COSV55004052; called by muse, mutect2, varscan2
- NEXMIF | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 123/152 reads (81%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV50032912, COSV99281438; called by muse, mutect2, varscan2
- NLRP9 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 249/609 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs200751354; called by muse, mutect2, varscan2
- NOS1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV57614688; called by muse, varscan2
- NOS1AP | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 286/638 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs768206947, COSV62633932; called by muse, mutect2, varscan2
- NPAS4 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 210/605 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs1387372421; called by muse, mutect2, varscan2
- NPR1 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 221/589 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs1417036582, COSV64117437; called by muse, mutect2, varscan2
- OBSCN | c.19892C>T p.S6631F | Missense Mutation (SNP) | VAF 337/775 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100804810; called by muse, mutect2, varscan2
- OR10G9 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 199/520 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV66686830; called by muse, mutect2, varscan2
- OR14C36 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 211/544 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV58602136, COSV58603027; called by muse, mutect2, varscan2
- OR1M1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 196/524 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.123); catalogued as COSV70036965; called by muse, mutect2, varscan2
- OR2A5 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 189/692 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs367636913; called by muse, mutect2, varscan2
- OR2T2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 129/444 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs752112863; called by muse, mutect2, varscan2
- OR4A16 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 180/462 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs575051490, COSV59042137; called by muse, mutect2, varscan2
- OR4C15 | c.359C>T p.S120F (on ENST00000314644; = p.S66F on NM_001001920.2) | Missense Mutation (SNP) | VAF 132/342 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.315); catalogued as COSV58952951; called by muse, mutect2, varscan2
- OR51B5 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 254/668 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1435926857, COSV56175601; called by muse, mutect2, varscan2
- OR8B8 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 121/243 reads (50%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV60144672; called by muse, mutect2, varscan2
- OTOP1 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 223/582 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs199742451, COSV56390298; called by muse, mutect2, varscan2
- PAAF1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100142631; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.371C>T p.P124L (on ENST00000259318 / NM_001136562.3; = p.P355L on NM_007203.5) | Missense Mutation (SNP) | VAF 129/287 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1204487280; called by muse, mutect2, varscan2
- PCDHA10 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 171/448 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV56514351; called by muse, mutect2, varscan2
- PCDHA4 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 369/880 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.237); catalogued as rs372115820; called by muse, mutect2, varscan2
- PCDHB10 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.182); catalogued as rs782290769, COSV53377610, COSV99505091; called by muse, mutect2
- PCDHB2 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 36/857 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.251); catalogued as COSV50564080; called by muse, mutect2
- PCDHB6 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 182/496 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV50694999, COSV99170729; called by muse, mutect2, varscan2
- PCLO | c.4829G>A p.R1610Q | Missense Mutation (SNP) | VAF 234/846 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV100434794; called by muse, mutect2, varscan2
- PDE1A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 221/562 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs145482728, COSV59527650; called by muse, mutect2, varscan2
- PELP1 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 168/393 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.921); catalogued as rs779956082; called by muse, mutect2, varscan2
- PIK3C2B | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 174/535 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs142302316, COSV65803314; called by muse, mutect2, varscan2
- PIK3C2B | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 196/387 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV65803521; called by muse, mutect2, varscan2
- PKD2L2 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.707); catalogued as COSV51797803; called by muse, mutect2, varscan2
- PLEKHG5 | c.2659C>T p.P887S (on ENST00000400915 / NM_001042663.3; = p.P850S on NM_020631.6) | Missense Mutation (SNP) | VAF 352/439 reads (80%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1365478515, COSV61068389; called by muse, mutect2, varscan2
- PLIN5 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 125/252 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV67850878; called by muse, mutect2, varscan2
- POSTN | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 171/719 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777253742; called by muse, mutect2, varscan2
- PPP1R3A | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 156/582 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV99492150; called by muse, mutect2, varscan2
- PRODH2 | c.731G>A p.R244Q (on ENST00000301175; = p.R168Q on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 165/400 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs780676051; called by muse, varscan2
- PRSS12 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.019); catalogued as COSV56606805; called by muse, mutect2, varscan2
- PTPRD | c.4676G>A p.R1559Q | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287979283, COSV100645160, COSV61975664; called by muse, mutect2, varscan2
- PTPRD | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 179/441 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV61981198; called by muse, mutect2, varscan2
- PXDNL | c.1804G>A p.G602S | Missense Mutation (SNP) | VAF 357/532 reads (67%) | SIFT tolerated (0.78); PolyPhen benign (0.07); catalogued as COSV62484821; called by muse, mutect2, varscan2
- RADIL | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 136/313 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1466354957, COSV68199288; called by muse, mutect2, varscan2
- RALGAPA1 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 160/414 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs769180156; called by muse, mutect2, varscan2
- RBFOX3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 154/364 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101332963; called by muse, mutect2, varscan2
- RGP1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 173/256 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as rs1563973513; called by muse, mutect2, varscan2
- RGPD4 | c.1526G>A p.S509N | Missense Mutation (SNP) | VAF 232/666 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100736494; called by muse, mutect2, varscan2
- RNASEH2B | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 402/722 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV60746774; called by muse, mutect2, varscan2
- RPH3AL | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 213/576 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58749661; called by muse, mutect2, varscan2
- RYR3 | c.14139+1G>A p.X4713_splice (on ENST00000389232; = p.X4714_splice on NM_001036.6) | Splice Site (SNP) | VAF 184/500 reads (37%) | catalogued as COSV66804958; called by muse, mutect2
- SCN5A | c.4996C>T p.L1666F (on ENST00000333535 / NM_198056.3; = p.L1665F on NM_000335.5) | Missense Mutation (SNP) | VAF 186/405 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61117830, COSV61120864; called by muse, mutect2, varscan2
- SCUBE3 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 151/568 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1313649538; called by muse, mutect2, varscan2
- SEC14L5 | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 114/269 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV52036879; called by muse, mutect2, varscan2
- SEMA5A | c.1786G>A p.G596R | Missense Mutation (SNP) | VAF 141/363 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218554013, COSV101228477, COSV66806423; called by muse, mutect2, varscan2
- SEMA5B | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 214/498 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766126034, COSV52094083; called by muse, mutect2, varscan2
- SERPINA9 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 156/250 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54072667; called by muse, mutect2, varscan2
- SGSM1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 214/560 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768962451, COSV68509585; called by muse, mutect2, varscan2
- SHISA9 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 252/637 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1321323622; called by muse, mutect2, varscan2
- SIGLEC5 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55784208; called by muse, mutect2, varscan2
- SIGLEC9 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 150/383 reads (39%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.529); catalogued as rs1375240808; called by muse, mutect2, varscan2
- SLC20A1 | c.1275A>G p.I425M | Missense Mutation (SNP) | VAF 218/543 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs772676810, COSV55610298; called by muse, mutect2, varscan2
- SLC30A8 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 190/766 reads (25%) | catalogued as rs374796913; called by muse, mutect2, varscan2
- SLC44A5 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 261/346 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63770918; called by muse, mutect2, varscan2
- SLC6A14 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 180/232 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100903214; called by muse, mutect2, varscan2
- SOX21 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 168/308 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs767667073; called by muse, mutect2, varscan2
- SP100 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs770957115, COSV50992063; called by muse, varscan2
- SPATA31E1 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 119/314 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs758967295; called by muse, mutect2, varscan2
- SPP2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 277/759 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as rs755087069, COSV51445088, COSV51445732; called by muse, mutect2, varscan2
- SPTA1 | c.6250G>A p.D2084N | Missense Mutation (SNP) | VAF 407/881 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.395); catalogued as COSV63755135; called by muse, mutect2, varscan2
- SPTA1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 231/635 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750863150, COSV63748627; called by muse, mutect2, varscan2
- STK31 | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 115/309 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV63456246; called by muse, mutect2, varscan2
- SYNGR1 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 151/364 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs760308694; called by muse, mutect2, varscan2
- TCF20 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 279/675 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.931); catalogued as rs767689409; called by muse, mutect2, varscan2
- TENM3 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV101305319; called by muse, mutect2, varscan2
- TESPA1 | c.566C>T p.P189L (on ENST00000316577 / NM_001098815.3; = p.P51L on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 206/502 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758911223; called by muse, mutect2, varscan2
- TESPA1 | c.565C>T p.P189S (on ENST00000316577 / NM_001098815.3; = p.P51S on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 208/507 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV100345507, COSV57257379; called by muse, mutect2, varscan2
- TLN2 | c.5263C>T p.L1755F | Missense Mutation (SNP) | VAF 155/420 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.058); catalogued as COSV60889369, COSV60896564; called by muse, mutect2, varscan2
- TMPRSS11E | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 155/465 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100542142; called by muse, mutect2, varscan2
- TREML1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 228/617 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs758242033; called by muse, mutect2, varscan2
- TTC21A | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 206/487 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs201948181; called by muse, mutect2, varscan2
- UBE3B | c.3092C>T p.P1031L | Missense Mutation (SNP) | VAF 165/417 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356441249; called by muse, mutect2, varscan2
- UBE4B | c.2071C>T p.L691F (on ENST00000343090 / NM_001105562.3; = p.L562F on NM_006048.5) | Missense Mutation (SNP) | VAF 339/413 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53540412; called by muse, mutect2, varscan2
- UGT2A3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 237/582 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV52360127; called by muse, mutect2, varscan2
- VWA7 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 112/419 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV63304584; called by muse, mutect2, varscan2
- WDR49 | c.2017G>A p.E673K (on ENST00000308378 / NM_001366158.1; = p.E1014K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 185/454 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as rs1373560612, COSV52984038; called by muse, mutect2, varscan2
- ACKR2 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 176/445 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- AHI1 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 154/238 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.11129C>T p.P3710L | Missense Mutation (SNP) | VAF 140/417 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ALPL | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 350/425 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.6841C>T p.Q2281* | Nonsense Mutation (SNP) | VAF 168/245 reads (69%) | called by muse, mutect2, varscan2
- ANKRD36 | c.3419C>T p.S1140F | Missense Mutation (SNP) | VAF 153/877 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AP4M1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 200/658 reads (30%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- APP | c.2053C>T p.H685Y | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ASAH2 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 235/728 reads (32%) | called by muse, mutect2, varscan2
- ASXL3 | c.4312G>A p.D1438N | Missense Mutation (SNP) | VAF 214/485 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- AURKA | c.1179C>A p.C393* | Nonsense Mutation (SNP) | VAF 354/650 reads (54%) | called by muse, mutect2, varscan2
- BCL11A | c.943G>A p.G315S (on ENST00000335712 / NM_001365609.1; = p.G349S on NM_018014.4) | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C2CD4C | c.650A>G p.D217G | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CACNA1H | c.5699C>T p.P1900L | Missense Mutation (SNP) | VAF 190/487 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CACNA1I | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 327/753 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALM3 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 209/499 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CAPRIN1 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 124/345 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASKIN1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 133/339 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPER1 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CCBE1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 205/563 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC168 | c.16816G>A p.D5606N | Missense Mutation (SNP) | VAF 162/608 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- CCDC168 | c.15242C>T p.P5081L | Missense Mutation (SNP) | VAF 148/563 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CCDC168 | c.9911G>A p.G3304E | Missense Mutation (SNP) | VAF 337/659 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CCL15 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 112/283 reads (40%) | called by muse, mutect2, varscan2
- CD1C | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 412/841 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CDH13 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 143/335 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CEP63 | c.1975C>T p.L659F | Missense Mutation (SNP) | VAF 97/253 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CFAP54 | c.3981G>A p.M1327I | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CNGA3 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 197/470 reads (42%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- DCHS2 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DENND1C | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- DMXL2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 120/298 reads (40%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH9 | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 221/611 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAJB9 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 247/889 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMT3L | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EBF1 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 179/440 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ELK1 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 131/167 reads (78%) | SIFT tolerated (0.68); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EML2 | c.1490G>A p.S497N | Missense Mutation (SNP) | VAF 136/354 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- EPDR1 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 176/494 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FAM186A | c.4669C>T p.P1557S | Missense Mutation (SNP) | VAF 243/752 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- FAM71A | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 296/585 reads (51%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- FAT4 | c.12985G>A p.D4329N | Missense Mutation (SNP) | VAF 133/338 reads (39%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FEM1A | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 204/553 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FERMT3 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 135/332 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FGFR1 | c.539C>T p.S180F (on ENST00000447712 / NM_023110.3; = p.S178F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 774/1116 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FOXD4 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2
- FOXK1 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 184/490 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAS2L2 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 162/399 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCM2 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 159/452 reads (35%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- GK2 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 226/608 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GLG1 | c.918T>A p.F306L | Missense Mutation (SNP) | VAF 198/541 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- GLT8D2 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 131/361 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GMPS | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 174/428 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GNRH2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 401/697 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GP2 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 158/381 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIN2A | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 221/564 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR5B | c.5893C>T p.L1965F | Missense Mutation (SNP) | VAF 155/370 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HOXB1 | c.825C>G p.C275W | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.076); called by muse, mutect2
- HTRA1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 193/305 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- HYDIN | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- IL17REL | c.-40G>A | Splice Region (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- INTU | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 136/354 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITPRID1 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 133/376 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- KDM4B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 135/394 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- KIAA0100 | c.1432T>A p.S478T | Missense Mutation (SNP) | VAF 195/458 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); called by muse, varscan2
- KIF17 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 256/308 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLRC1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 186/453 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- KMT2C | c.14727G>A p.W4909* | Nonsense Mutation (SNP) | VAF 122/412 reads (30%) | called by muse, mutect2, varscan2
- KPNA3 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 143/515 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- KRT13 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 227/608 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- KRT38 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 262/682 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- KRT8 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 171/419 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- KRT82 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 181/504 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- LEF1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 202/550 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- LIN37 | c.35-4C>T | Splice Region (SNP) | VAF 100/302 reads (33%) | called by muse, mutect2, varscan2
- LONRF2 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 196/520 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- LPIN1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 164/391 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRCH2 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 104/122 reads (85%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRGUK | c.2078C>G p.P693R | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- LRGUK | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 243/845 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.5204C>T p.P1735L | Missense Mutation (SNP) | VAF 121/339 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP2 | c.7693C>T p.L2565F | Missense Mutation (SNP) | VAF 167/494 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LRRC14B | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC37A3 | c.3817A>G p.K1273E | Missense Mutation (SNP) | VAF 178/484 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRRC37A3 | c.3054G>A p.L1018= | Splice Region (SNP) | VAF 265/680 reads (39%) | called by muse, mutect2, varscan2
- LUC7L | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 136/362 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAGEL2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 34/756 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.856); called by muse, mutect2
- MKRN2OS | c.31A>T p.I11F | Missense Mutation (SNP) | VAF 203/537 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MMP27 | c.1160A>T p.K387I | Missense Mutation (SNP) | VAF 130/376 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MROH2B | c.1682A>G p.E561G | Missense Mutation (SNP) | VAF 138/386 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MSTN | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 205/508 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- MTNR1A | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 124/329 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- MUC12 | c.11248C>T p.H3750Y (on ENST00000379442; = p.H3607Y on NM_001164462.1) | Missense Mutation (SNP) | VAF 49/1253 reads (4%) | SIFT tolerated (0.2); called by muse, mutect2
- MUC12 | c.12079T>A p.F4027I (on ENST00000379442; = p.F3884I on NM_001164462.1) | Missense Mutation (SNP) | VAF 128/267 reads (48%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- MUC16 | c.42389C>T p.S14130F | Missense Mutation (SNP) | VAF 107/251 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MUC3A | c.5042C>T p.S1681F | Missense Mutation (SNP) | VAF 171/1153 reads (15%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MUC5AC | c.11069C>T p.S3690F | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MVP | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 139/366 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- MYBPC1 | c.472G>A p.E158K (on ENST00000550270 / NM_206820.2; = p.E183K on NM_002465.4) | Missense Mutation (SNP) | VAF 180/490 reads (37%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NDST4 | c.2413G>A p.G805S | Missense Mutation (SNP) | VAF 119/292 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP3 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 215/672 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOS1 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 330/874 reads (38%) | called by muse, varscan2
- NOTCH1 | c.7342C>T p.P2448S | Missense Mutation (SNP) | VAF 135/370 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSA2 | c.626C>A p.T209K | Missense Mutation (SNP) | VAF 254/608 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NTF3 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 152/401 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OBSL1 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 172/452 reads (38%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OLFM2 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 150/385 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- OR2W1 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 162/606 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- OR4B1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 120/347 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4E1 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.089); called by muse, mutect2
- OR6S1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 184/437 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8G5 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 128/323 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR8U1 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 170/670 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPOLB | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 168/432 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARP4 | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHA12 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 155/408 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCNX2 | c.3848T>C p.L1283P | Missense Mutation (SNP) | VAF 268/714 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLB1 | c.1590C>A p.F530L | Missense Mutation (SNP) | VAF 156/427 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- PLCH1 | c.3644C>T p.S1215F (on ENST00000340059 / NM_001130960.2; = p.S1207F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/424 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PLEKHG4 | c.1509+2T>G p.X503_splice | Splice Site (SNP) | VAF 113/282 reads (40%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 116/331 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- POF1B | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 84/109 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- POTEA | c.1467G>A p.M489I (on ENST00000519951 / NM_001005365.2; = p.M443I on NM_001002920.1) | Missense Mutation (SNP) | VAF 161/750 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRIM2 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 208/452 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PRR23B | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 250/612 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTK2 | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 291/1382 reads (21%) | called by muse, mutect2, varscan2
- PTPRR | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 262/621 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- PTPRT | c.2325T>A p.Y775* | Nonsense Mutation (SNP) | VAF 171/286 reads (60%) | called by muse, mutect2, varscan2
- RAMP3 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 158/423 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RBL1 | c.492G>A p.R164= | Splice Region (SNP) | VAF 110/480 reads (23%) | called by muse, mutect2, varscan2
- RBL1 | c.492-1G>A p.X164_splice | Splice Site (SNP) | VAF 109/479 reads (23%) | called by muse, mutect2, varscan2
- RBMXL3 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 168/195 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- RFPL3 | c.485G>A p.R162K (on ENST00000249007 / NM_001098535.1; = p.R133K on NM_006604.2) | Missense Mutation (SNP) | VAF 251/657 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- RFPL4AL1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 89/818 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RFX7 | c.139C>T p.P47S (on ENST00000559447 / NM_001368074.1; = p.P144S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/418 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- RGPD2 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 86/427 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIC1 | c.3001-5C>T | Splice Region (SNP) | VAF 174/438 reads (40%) | called by muse, mutect2, varscan2
- RIMS1 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 151/381 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RORC | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 156/422 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RRN3 | c.207T>G p.N69K | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RUNDC1 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 169/418 reads (40%) | called by muse, mutect2, varscan2
- SCARA5 | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 448/678 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SERPINB6 | c.344G>C p.G115A (on ENST00000612421 / NM_001271823.2; = p.G96A on NM_004568.6) | Missense Mutation (SNP) | VAF 285/527 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SERPINB6 | c.343G>A p.G115R (on ENST00000612421 / NM_001271823.2; = p.G96R on NM_004568.6) | Missense Mutation (SNP) | VAF 286/530 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SH2D4B | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 260/343 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SKP1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 245/574 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC7A5 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 307/776 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SLCO1A2 | c.1879C>T p.H627Y | Missense Mutation (SNP) | VAF 239/550 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMYD2 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 188/445 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA22 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- SPOCK2 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 147/223 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPPL2C | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 233/601 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- TAP2 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 353/700 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBX15 | c.1682G>A p.G561E (on ENST00000369429 / NM_001330677.2; = p.G455E on NM_152380.3) | Missense Mutation (SNP) | VAF 344/670 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TECPR2 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 101/159 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TLN2 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 132/299 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM209 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 114/496 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMPRSS6 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 218/544 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- TMTC4 | c.551C>T p.S184F (on ENST00000376234 / NM_001350577.2; = p.S203F on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 184/652 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TOPAZ1 | c.227A>T p.K76M | Missense Mutation (SNP) | VAF 202/589 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TOX2 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 135/515 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TSHZ2 | c.1746G>A p.W582* | Nonsense Mutation (SNP) | VAF 130/496 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.36880A>G p.K12294E (on ENST00000591111; = p.K4870E on NM_003319.4) | Missense Mutation (SNP) | VAF 174/406 reads (43%) | PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ULK2 | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- USP34 | c.5984C>T p.P1995L | Missense Mutation (SNP) | VAF 149/381 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VPS50 | c.1682G>T p.S561I | Missense Mutation (SNP) | VAF 294/516 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- VWA7 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 112/417 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WNT10A | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 195/537 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZC3H4 | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF133 | c.1132G>T p.G378W (on ENST00000316358 / NM_001352454.2; = p.G377W on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 145/823 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF169 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 122/309 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF18 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 211/555 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF404 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 150/385 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ZNF444 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 177/485 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ZNF567 | c.853C>T p.Q285* (on ENST00000536254 / NM_001322913.1; = p.Q254* on NM_152603.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 130/310 reads (42%) | called by muse, mutect2
- ZNF609 | c.747G>A p.K249= | Splice Region (SNP) | VAF 120/261 reads (46%) | called by muse, mutect2, varscan2
- ZNF648 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 271/597 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ZNF653 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 154/397 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF655 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 288/554 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ABCC8 | c.2754G>A p.R918= | Silent (SNP) | VAF 156/422 reads (37%) | catalogued as rs1270757878, COSV56857698; called by muse, mutect2, varscan2
- AC008397.2 | c.1263C>T p.A421= | Silent (SNP) | VAF 134/333 reads (40%) | called by muse, mutect2, varscan2
- ACKR3 | c.81C>T p.I27= | Silent (SNP) | VAF 124/375 reads (33%) | catalogued as rs767699327, COSV56021110; called by muse, mutect2, varscan2
- ACVR1 | c.1149C>T p.A383= | Silent (SNP) | VAF 215/473 reads (45%) | called by muse, mutect2, varscan2
- AGAP9 | c.1068C>T p.S356= | Silent (SNP) | VAF 32/450 reads (7%) | called by muse, mutect2
- ALDH5A1 | c.1434C>T p.I478= | Silent (SNP) | VAF 402/748 reads (54%) | called by muse, mutect2, varscan2
- ANKRD2 | c.393C>T p.A131= | Silent (SNP) | VAF 251/359 reads (70%) | called by muse, mutect2, varscan2
- ANO4 | c.1509C>T p.I503= (on ENST00000392977 / NM_001286615.2; = p.I468= on NM_178826.4) | Silent (SNP) | VAF 174/396 reads (44%) | catalogued as rs745433802, COSV100151947; called by muse, mutect2, varscan2
- APOB | c.3579C>T p.F1193= | Silent (SNP) | VAF 154/365 reads (42%) | catalogued as rs267599187, COSV51922866; called by muse, mutect2, varscan2
- ASMT | c.598C>T p.L200= (on ENST00000381229; = p.L228= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 323/852 reads (38%) | called by muse, mutect2, varscan2
- ASTN1 | c.3849C>T p.I1283= | Silent (SNP) | VAF 354/718 reads (49%) | catalogued as COSV62507292; called by muse, mutect2, varscan2
- ATMIN | c.372G>A p.L124= | Silent (SNP) | VAF 150/397 reads (38%) | catalogued as COSV55146400; called by muse, mutect2, varscan2
- ATP1A2 | c.465C>T p.I155= | Silent (SNP) | VAF 234/702 reads (33%) | catalogued as COSV63404712; called by muse, mutect2, varscan2
- BCL2L12 | c.9G>A p.R3= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs755216778, COSV55862200; called by muse, mutect2, varscan2
- BPIFB4 | c.348G>A p.R116= | Silent (SNP) | VAF 273/451 reads (61%) | catalogued as rs780218690; called by muse, mutect2, varscan2
- C10orf71 | c.2874C>T p.F958= | Silent (SNP) | VAF 95/226 reads (42%) | called by muse, mutect2, varscan2
- CACNA1H | c.4410G>A p.K1470= | Silent (SNP) | VAF 259/673 reads (38%) | catalogued as rs909381456; called by muse, mutect2, varscan2
- CACTIN | c.1017C>T p.A339= | Silent (SNP) | VAF 197/521 reads (38%) | catalogued as rs747058525; called by muse, mutect2, varscan2
- CCDC134 | c.420C>T p.I140= | Silent (SNP) | VAF 261/684 reads (38%) | catalogued as rs1300993254; called by muse, mutect2, varscan2
- CDH22 | c.420G>A p.R140= | Silent (SNP) | VAF 104/400 reads (26%) | called by muse, mutect2, varscan2
- CDRT1 | c.1926C>T p.F642= | Silent (SNP) | VAF 343/890 reads (39%) | catalogued as COSV100599784, COSV100600022; called by muse, mutect2
- CELSR3 | c.5037C>T p.L1679= | Silent (SNP) | VAF 205/550 reads (37%) | called by muse, mutect2, varscan2
- CFAP99 | c.279C>T p.F93= | Silent (SNP) | VAF 262/734 reads (36%) | called by muse, mutect2
- CLIC6 | c.1497G>A p.L499= (on ENST00000360731 / NM_001317009.2; = p.L481= on NM_053277.3) | Silent (SNP) | VAF 189/486 reads (39%) | catalogued as rs1459536552, COSV62448245; called by muse, mutect2, varscan2
- CLK2 | c.309G>A p.R103= | Silent (SNP) | VAF 302/741 reads (41%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.2478C>T p.S826= | Silent (SNP) | VAF 181/422 reads (43%) | called by muse, varscan2
- COBL | c.2253C>T p.S751= | Silent (SNP) | VAF 79/202 reads (39%) | called by muse, mutect2, varscan2
- COL7A1 | c.6888G>A p.G2296= | Silent (SNP) | VAF 158/435 reads (36%) | catalogued as rs1471254676; called by muse, mutect2, varscan2
- CPE | c.1365G>A p.R455= | Silent (SNP) | VAF 88/282 reads (31%) | called by muse, mutect2, varscan2
- CSF3R | c.1149C>T p.A383= | Silent (SNP) | VAF 274/330 reads (83%) | catalogued as rs1300070600; called by muse, mutect2, varscan2
- CSMD1 | c.4290C>T p.I1430= (on ENST00000520002; = p.I1429= on NM_033225.6) | Silent (SNP) | VAF 236/1160 reads (20%) | called by muse, mutect2, varscan2
- CTSG | c.447G>A p.R149= | Silent (SNP) | VAF 124/310 reads (40%) | catalogued as rs934809449; called by muse, mutect2, varscan2
- CYBRD1 | c.582C>T p.F194= | Silent (SNP) | VAF 143/373 reads (38%) | catalogued as rs868611331; called by muse, mutect2, varscan2
- DAG1 | c.2538C>T p.T846= | Silent (SNP) | VAF 132/311 reads (42%) | catalogued as COSV100444852; called by muse, mutect2, varscan2
- DGAT1 | c.930C>T p.P310= | Silent (SNP) | VAF 216/899 reads (24%) | called by muse, mutect2, varscan2
- DIS3L2 | c.1866G>A p.V622= | Silent (SNP) | VAF 170/441 reads (39%) | called by muse, mutect2, varscan2
- DNAH14 | c.9342G>A p.L3114= (on ENST00000445597; = p.L4122= on NM_001367479.1) | Silent (SNP) | VAF 226/683 reads (33%) | called by muse, mutect2, varscan2
- DNAH17 | c.12210G>A p.L4070= | Silent (SNP) | VAF 142/413 reads (34%) | called by muse, mutect2, varscan2
- DNAH3 | c.6294C>T p.P2098= | Silent (SNP) | VAF 260/518 reads (50%) | called by muse, mutect2, varscan2
- DOP1B | c.5506C>T p.L1836= | Silent (SNP) | VAF 211/527 reads (40%) | called by muse, mutect2, varscan2
- DSC3 | c.1608G>A p.E536= | Silent (SNP) | VAF 129/395 reads (33%) | catalogued as rs140923080, COSV64574868; called by muse, mutect2, varscan2
- DSC3 | c.483T>A p.S161= | Silent (SNP) | VAF 72/187 reads (39%) | called by mutect2, varscan2
- DSP | c.5622G>A p.K1874= | Silent (SNP) | VAF 164/610 reads (27%) | catalogued as COSV65793803; called by muse, mutect2, varscan2
- DTYMK | c.597C>T p.I199= | Silent (SNP) | VAF 211/534 reads (40%) | called by muse, mutect2, varscan2
- ENAM | c.753G>A p.T251= | Silent (SNP) | VAF 197/462 reads (43%) | catalogued as rs760680070, COSV68535329; called by muse, mutect2, varscan2
- EPHA10 | c.1353C>T p.P451= | Silent (SNP) | VAF 157/192 reads (82%) | called by muse, mutect2, varscan2
- EPHA8 | c.1911C>T p.I637= | Silent (SNP) | VAF 497/605 reads (82%) | catalogued as rs774864430; called by muse, mutect2, varscan2
- EPHB6 | c.2985C>T p.T995= | Silent (SNP) | VAF 318/558 reads (57%) | catalogued as COSV63892767; called by muse, mutect2, varscan2
- ESAM | c.1065T>C p.P355= | Silent (SNP) | VAF 109/275 reads (40%) | called by muse, mutect2, varscan2
- EVI5L | c.2241C>T p.A747= | Silent (SNP) | VAF 114/321 reads (36%) | catalogued as rs1323209634; called by muse, mutect2, varscan2
- FCSK | c.3254G>A p.*1085= | Silent (SNP) | VAF 91/263 reads (35%) | catalogued as COSV99851344; called by muse, mutect2, varscan2
- FEZF1 | c.1410C>T p.L470= | Silent (SNP) | VAF 159/575 reads (28%) | catalogued as COSV58659906; called by muse, mutect2, varscan2
- FIBP | c.1011C>T p.S337= (on ENST00000338369 / NM_198897.2; = p.S330= on NM_004214.5) | Silent (SNP) | VAF 138/378 reads (37%) | called by muse, mutect2, varscan2
- FLRT2 | c.1827C>T p.I609= | Silent (SNP) | VAF 108/161 reads (67%) | catalogued as rs1355606166, COSV58136058; called by muse, mutect2, varscan2
- FMO2 | c.276G>A p.R92= | Silent (SNP) | VAF 151/444 reads (34%) | catalogued as COSV52947130; called by muse, mutect2, varscan2
- FRMPD3 | c.2109C>T p.P703= | Silent (SNP) | VAF 156/182 reads (86%) | called by muse, varscan2
- FSIP2 | c.18798T>C p.S6266= | Silent (SNP) | VAF 24/487 reads (5%) | catalogued as rs1175631223; called by muse, mutect2
- FTMT | c.345C>T p.F115= | Silent (SNP) | VAF 164/409 reads (40%) | catalogued as COSV58420038; called by muse, mutect2, varscan2
- FUT5 | c.891C>T p.F297= | Silent (SNP) | VAF 109/534 reads (20%) | catalogued as COSV99399007; called by muse, mutect2
- GABRA2 | c.732C>T p.F244= | Silent (SNP) | VAF 130/329 reads (40%) | catalogued as COSV62913501; called by muse, mutect2, varscan2
- GAGE10 | c.183G>A p.E61= | Silent (SNP) | VAF 88/723 reads (12%) | called by muse, mutect2, varscan2
- GALNT8 | c.1161G>A p.E387= | Silent (SNP) | VAF 86/268 reads (32%) | catalogued as COSV52901636; called by muse, mutect2, varscan2
- GBP7 | c.213G>A p.V71= | Silent (SNP) | VAF 409/487 reads (84%) | called by muse, mutect2, varscan2
- GIT1 | c.462C>T p.S154= | Silent (SNP) | VAF 154/478 reads (32%) | called by muse, mutect2, varscan2
- GLYATL3 | c.750G>A p.L250= | Silent (SNP) | VAF 146/293 reads (50%) | catalogued as rs754058745; called by muse, mutect2, varscan2
- GPR139 | c.384C>T p.I128= | Silent (SNP) | VAF 160/406 reads (39%) | catalogued as rs775925795, COSV58501465, COSV58502536; called by muse, mutect2, varscan2
- GPRC6A | c.1872G>A p.V624= | Silent (SNP) | VAF 213/303 reads (70%) | catalogued as COSV59951787, COSV59955462; called by muse, mutect2, varscan2
- GRIA2 | c.1434G>A p.T478= | Silent (SNP) | VAF 171/467 reads (37%) | catalogued as rs745408425, COSV52391837; called by muse, mutect2, varscan2
- GRID2 | c.1029G>A p.E343= | Silent (SNP) | VAF 154/364 reads (42%) | called by muse, mutect2, varscan2
- GTDC1 | c.1302C>T p.I434= (on ENST00000344850 / NM_001354361.1; = p.I349= on NM_024659.6 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 175/447 reads (39%) | catalogued as rs766531753, COSV53994981; called by muse, mutect2, varscan2
- HDGFL1 | c.450G>A p.G150= | Silent (SNP) | VAF 525/933 reads (56%) | called by muse, varscan2
- HEPHL1 | c.837C>T p.F279= | Silent (SNP) | VAF 138/427 reads (32%) | catalogued as COSV59889689; called by muse, mutect2
- HEPHL1 | c.1095C>T p.N365= | Silent (SNP) | VAF 166/415 reads (40%) | catalogued as rs757924456; called by muse, mutect2, varscan2
- HPS4 | c.1404C>T p.P468= | Silent (SNP) | VAF 127/328 reads (39%) | called by muse, mutect2, varscan2
- HRNR | c.2862C>T p.S954= | Silent (SNP) | VAF 235/507 reads (46%) | called by muse, mutect2, varscan2
- HTT | c.8082C>T p.A2694= | Silent (SNP) | VAF 144/337 reads (43%) | catalogued as rs1411269706; called by muse, mutect2, varscan2
- IL22 | c.15G>A p.Q5= | Silent (SNP) | VAF 127/357 reads (36%) | catalogued as COSV60160694; called by muse, mutect2, varscan2
- IL2RB | c.1212C>T p.S404= | Silent (SNP) | VAF 152/393 reads (39%) | called by muse, mutect2, varscan2
- INSC | c.1116C>T p.I372= | Silent (SNP) | VAF 172/437 reads (39%) | catalogued as rs564607638, COSV65409732; called by muse, mutect2, varscan2
- IVL | c.1207C>T p.L403= | Silent (SNP) | VAF 283/852 reads (33%) | called by muse, mutect2, varscan2
- JAML | c.723G>A p.L241= (on ENST00000356289 / NM_001098526.2; = p.L231= on NM_153206.3) | Silent (SNP) | VAF 185/422 reads (44%) | called by muse, mutect2, varscan2
- KCNJ10 | c.1065C>T p.L355= | Silent (SNP) | VAF 256/698 reads (37%) | called by muse, mutect2, varscan2
- KCNJ18 | c.480C>T p.F160= | Silent (SNP) | VAF 207/584 reads (35%) | called by muse, varscan2
- KCNK1 | c.616C>T p.L206= | Silent (SNP) | VAF 342/951 reads (36%) | called by muse, mutect2, varscan2
- KCNK10 | c.798C>T p.S266= | Silent (SNP) | VAF 163/252 reads (65%) | called by muse, mutect2, varscan2
- KCNK16 | c.132G>A p.R44= | Silent (SNP) | VAF 146/556 reads (26%) | called by muse, mutect2, varscan2
- KCNK9 | c.519C>T p.I173= | Silent (SNP) | VAF 634/942 reads (67%) | catalogued as COSV57281525; called by muse, mutect2, varscan2
- KCNMB2 | c.102G>A p.R34= | Silent (SNP) | VAF 137/358 reads (38%) | catalogued as COSV64201022; called by muse, mutect2, varscan2
- KCNT2 | c.2892G>A p.Q964= | Silent (SNP) | VAF 179/506 reads (35%) | called by muse, mutect2, varscan2
- KIF4B | c.3174T>G p.G1058= | Silent (SNP) | VAF 296/768 reads (39%) | called by mutect2, varscan2
- KIR2DL3 | c.138C>T p.I46= | Silent (SNP) | VAF 202/715 reads (28%) | catalogued as rs868605760; called by muse, mutect2, varscan2
- KLF13 | c.618G>A p.K206= | Silent (SNP) | VAF 128/344 reads (37%) | called by muse, mutect2, varscan2
- KLHL13 | c.1746C>T p.V582= | Silent (SNP) | VAF 203/245 reads (83%) | catalogued as rs373625143, COSV53249360; called by muse, mutect2, varscan2
- KRT12 | c.1209G>A p.A403= | Silent (SNP) | VAF 173/464 reads (37%) | called by muse, mutect2, varscan2
- KRT8 | c.270G>A p.Q90= | Silent (SNP) | VAF 158/400 reads (40%) | catalogued as rs770608699; called by muse, varscan2
- KRT80 | c.768G>A p.K256= | Silent (SNP) | VAF 177/396 reads (45%) | catalogued as rs1197296650, COSV57551441; called by muse, mutect2, varscan2
- KSR2 | c.315C>T p.V105= | Silent (SNP) | VAF 119/338 reads (35%) | catalogued as rs761993761, COSV60378325; called by muse, mutect2, varscan2
- KYNU | c.156G>A p.Q52= | Silent (SNP) | VAF 92/284 reads (32%) | catalogued as rs375522416; called by muse, mutect2, varscan2
- LDB2 | c.780G>A p.R260= | Silent (SNP) | VAF 238/625 reads (38%) | catalogued as COSV58767498; called by muse, mutect2, varscan2
- LPO | c.264A>T p.G88= | Silent (SNP) | VAF 288/620 reads (46%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.147G>A p.L49= | Silent (SNP) | VAF 125/910 reads (14%) | called by muse, mutect2, varscan2
- LRRC4 | c.1389G>A p.E463= | Silent (SNP) | VAF 477/811 reads (59%) | called by muse, mutect2, varscan2
- LRRC69 | c.1023C>T p.L341= | Silent (SNP) | VAF 419/679 reads (62%) | called by muse, mutect2, varscan2
- LRRIQ1 | c.1620C>T p.I540= | Silent (SNP) | VAF 158/496 reads (32%) | called by muse, mutect2, varscan2
- LTBP3 | c.1872C>T p.P624= | Silent (SNP) | VAF 102/258 reads (40%) | called by muse, mutect2, varscan2
- MAML1 | c.2196C>T p.P732= | Silent (SNP) | VAF 236/545 reads (43%) | called by muse, mutect2, varscan2
- MARK2 | c.1494C>T p.S498= (on ENST00000402010 / NM_001039469.2; = p.S497= on NM_004954.5) | Silent (SNP) | VAF 133/362 reads (37%) | called by muse, mutect2, varscan2
- MAZ | c.1422C>T p.S474= | Silent (SNP) | VAF 192/487 reads (39%) | called by muse, mutect2, varscan2
- MRAS | c.102C>T p.F34= | Silent (SNP) | VAF 216/525 reads (41%) | catalogued as COSV56673662; called by muse, mutect2, varscan2
- MUC17 | c.12246G>A p.T4082= | Silent (SNP) | VAF 279/920 reads (30%) | catalogued as rs201108444, COSV100072640; called by muse, mutect2, varscan2
- MUC22 | c.3714C>T p.V1238= | Silent (SNP) | VAF 394/1948 reads (20%) | called by muse, varscan2
- MUC3A | c.3639C>T p.F1213= | Silent (SNP) | VAF 268/468 reads (57%) | called by muse, mutect2, varscan2
- MUC5AC | c.1521G>A p.G507= | Silent (SNP) | VAF 91/252 reads (36%) | called by muse, mutect2, varscan2
- MYO3A | c.3684G>A p.R1228= | Silent (SNP) | VAF 217/494 reads (44%) | catalogued as COSV56318217; called by muse, mutect2, varscan2
- MYOCD | c.2757C>T p.F919= | Silent (SNP) | VAF 249/576 reads (43%) | catalogued as rs200336311, COSV58503952; called by muse, mutect2, varscan2
- MYT1L | c.2154C>T p.F718= | Silent (SNP) | VAF 187/508 reads (37%) | catalogued as rs1240511537, COSV101220894; called by muse, mutect2, varscan2
- NADSYN1 | c.777C>T p.S259= | Silent (SNP) | VAF 77/225 reads (34%) | called by muse, mutect2, varscan2
- NDRG3 | c.762T>C p.C254= (on ENST00000349004 / NM_032013.4; = p.C242= on NM_022477.4) | Silent (SNP) | VAF 149/469 reads (32%) | called by muse, mutect2, varscan2
- NLRP3 | c.687G>A p.G229= | Silent (SNP) | VAF 216/670 reads (32%) | catalogued as COSV60220849; called by muse, mutect2
- NLRP5 | c.2790G>A p.L930= | Silent (SNP) | VAF 124/274 reads (45%) | called by muse, varscan2
- NLRP7 | c.384G>A p.E128= | Silent (SNP) | VAF 185/484 reads (38%) | called by muse, mutect2, varscan2
- NLRP8 | c.2271G>A p.G757= | Silent (SNP) | VAF 191/388 reads (49%) | catalogued as rs931058663; called by muse, mutect2, varscan2
- NPY2R | c.903G>A p.K301= | Silent (SNP) | VAF 242/605 reads (40%) | catalogued as rs1372991636, COSV61527434; called by muse, mutect2, varscan2
- NRXN2 | c.2634C>T p.F878= | Silent (SNP) | VAF 213/532 reads (40%) | called by muse, mutect2, varscan2
- NUGGC | c.1662G>A p.L554= | Silent (SNP) | VAF 185/887 reads (21%) | called by muse, mutect2, varscan2
- OR4C15 | c.171C>T p.N57= (on ENST00000314644; = p.N3= on NM_001001920.2) | Silent (SNP) | VAF 169/411 reads (41%) | catalogued as rs1381885323, COSV58954562; called by muse, mutect2, varscan2
- OR4X1 | c.426C>T p.L142= | Silent (SNP) | VAF 227/498 reads (46%) | catalogued as rs780939167; called by muse, mutect2, varscan2
- OR51A7 | c.217C>T p.L73= | Silent (SNP) | VAF 181/519 reads (35%) | catalogued as rs756314063, COSV100834674, COSV63788173; called by muse, mutect2, varscan2
- OR5D13 | c.192C>T p.F64= | Silent (SNP) | VAF 209/549 reads (38%) | catalogued as rs1372658586, COSV100686783, COSV62333353; called by muse, mutect2, varscan2
- OR5D14 | c.645C>T p.I215= | Silent (SNP) | VAF 202/475 reads (43%) | catalogued as rs267602975; called by muse, mutect2, varscan2
- OR5H6 | c.6C>T p.F2= | Silent (SNP) | VAF 233/580 reads (40%) | catalogued as COSV67351789; called by muse, mutect2, varscan2
- OR5V1 | c.102T>C p.T34= | Silent (SNP) | VAF 387/688 reads (56%) | called by muse, mutect2, varscan2
- OR6A2 | c.534C>T p.I178= | Silent (SNP) | VAF 206/543 reads (38%) | catalogued as COSV60265445; called by muse, mutect2, varscan2
- OR6P1 | c.840C>T p.I280= | Silent (SNP) | VAF 302/591 reads (51%) | called by muse, mutect2, varscan2
- OR7G2 | c.585C>T p.I195= | Silent (SNP) | VAF 117/289 reads (40%) | catalogued as COSV59688391; called by muse, mutect2, varscan2
- OR8A1 | c.696G>A p.G232= | Silent (SNP) | VAF 192/476 reads (40%) | catalogued as COSV52508725; called by muse, mutect2, varscan2
- OR8J3 | c.219C>T p.N73= | Silent (SNP) | VAF 241/645 reads (37%) | called by muse, mutect2, varscan2
- OSGIN2 | c.1122T>C p.D374= | Silent (SNP) | VAF 146/724 reads (20%) | called by muse, mutect2, varscan2
- P2RY12 | c.693G>A p.R231= | Silent (SNP) | VAF 183/433 reads (42%) | catalogued as COSV56397675; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.372C>T p.P124= (on ENST00000259318 / NM_001136562.3; = p.P355= on NM_007203.5) | Silent (SNP) | VAF 127/284 reads (45%) | catalogued as rs1271564011; called by muse, mutect2, varscan2
- PCDHA3 | c.735G>A p.T245= | Silent (SNP) | VAF 216/496 reads (44%) | catalogued as rs782471663, COSV65364891; called by muse, mutect2, varscan2
- PCSK4 | c.984G>A p.Q328= | Silent (SNP) | VAF 194/534 reads (36%) | catalogued as COSV99029015; called by muse, mutect2
- PROSER1 | c.2607C>T p.G869= | Silent (SNP) | VAF 305/535 reads (57%) | catalogued as rs761087358; called by muse, mutect2, varscan2
- PRR12 | c.1320G>A p.E440= (on ENST00000615927; = p.E1261= on NM_020719.3) | Silent (SNP) | VAF 138/393 reads (35%) | catalogued as rs1568424525; called by muse, mutect2, varscan2
- PRR23B | c.295C>T p.L99= | Silent (SNP) | VAF 247/641 reads (39%) | catalogued as COSV100271933; called by muse, mutect2, varscan2
- PRR35 | c.705C>T p.F235= | Silent (SNP) | VAF 95/221 reads (43%) | called by muse, mutect2, varscan2
- PSG3 | c.606C>T p.L202= | Silent (SNP) | VAF 176/477 reads (37%) | catalogued as rs118018571; called by muse, mutect2, varscan2
- PTPRN2 | c.2103G>A p.P701= | Silent (SNP) | VAF 387/702 reads (55%) | catalogued as rs751000558; called by muse, mutect2, varscan2
- PTPRT | c.396G>A p.G132= | Silent (SNP) | VAF 278/481 reads (58%) | called by muse, mutect2, varscan2
- RAG2 | c.1554G>A p.K518= | Silent (SNP) | VAF 161/404 reads (40%) | catalogued as COSV57559259; called by muse, mutect2, varscan2
- RFLNB | c.327C>T p.T109= | Silent (SNP) | VAF 127/317 reads (40%) | called by muse, mutect2, varscan2
- RFPL4A | c.438C>T p.F146= | Silent (SNP) | VAF 95/852 reads (11%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.438C>T p.F146= | Silent (SNP) | VAF 89/890 reads (10%) | called by muse, mutect2
- RGL1 | c.1269C>T p.F423= (on ENST00000360851 / NM_001297672.2; = p.F458= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 197/475 reads (41%) | catalogued as COSV100486341; called by muse, mutect2, varscan2
- RIMS2 | c.1314G>A p.R438= (on ENST00000666250 / NM_001348490.2; = p.R246= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 130/567 reads (23%) | catalogued as rs1471953513; called by muse, mutect2, varscan2
- SALL3 | c.1005G>A p.S335= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as COSV73306027; called by muse, mutect2, varscan2
- SAMD9 | c.2761C>T p.L921= | Silent (SNP) | VAF 224/870 reads (26%) | called by muse, mutect2, varscan2
- SGIP1 | c.1326C>T p.S442= | Silent (SNP) | VAF 351/448 reads (78%) | catalogued as COSV99392604; called by muse, mutect2, varscan2
- SIGLEC5 | c.1593G>A p.R531= | Silent (SNP) | VAF 181/471 reads (38%) | catalogued as rs1380236906; called by muse, mutect2, varscan2
- SIK1B | c.1987T>C p.L663= | Silent (SNP) | VAF 61/159 reads (38%) | called by muse, mutect2, varscan2
- SIRT7 | c.114G>A p.K38= | Silent (SNP) | VAF 108/292 reads (37%) | called by muse, mutect2, varscan2
- SLC22A25 | c.1254C>T p.T418= | Silent (SNP) | VAF 218/575 reads (38%) | catalogued as rs1162986675; called by muse, mutect2, varscan2
- SLC25A48 | c.717C>T p.V239= (on ENST00000650267; = p.V185= on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 192/554 reads (35%) | catalogued as rs551720758; called by muse, mutect2, varscan2
- SLC44A5 | c.513G>A p.A171= | Silent (SNP) | VAF 342/444 reads (77%) | catalogued as rs762534368, COSV63762599; called by muse, mutect2, varscan2
- SLCO1A2 | c.1539C>T p.F513= | Silent (SNP) | VAF 172/507 reads (34%) | catalogued as COSV56611148; called by muse, mutect2, varscan2
- SOAT2 | c.453G>A p.L151= | Silent (SNP) | VAF 124/292 reads (42%) | called by muse, mutect2, varscan2
- SORL1 | c.2649C>T p.L883= | Silent (SNP) | VAF 133/371 reads (36%) | catalogued as rs1362451877, COSV52764394; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTLC1 | c.672A>G p.Q224= | Silent (SNP) | VAF 171/403 reads (42%) | called by muse, mutect2, varscan2
- STRN4 | c.1330C>T p.L444= | Silent (SNP) | VAF 182/485 reads (38%) | called by muse, mutect2, varscan2
- TBC1D2B | c.2778G>A p.E926= (on ENST00000300584 / NM_144572.1; = p.R909K on NM_015079.6) | Silent (SNP) | VAF 179/469 reads (38%) | called by muse, mutect2, varscan2
- TBC1D3L | c.1635C>T p.F545= | Silent (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.1296C>T p.V432= | Silent (SNP) | VAF 238/586 reads (41%) | called by muse, mutect2, varscan2
- TGFBR3 | c.1386C>T p.I462= | Silent (SNP) | VAF 250/320 reads (78%) | catalogued as rs750054560; called by muse, mutect2, varscan2
- TGM6 | c.873C>T p.A291= | Silent (SNP) | VAF 558/1003 reads (56%) | called by muse, mutect2, varscan2
- THOC5 | c.903C>T p.F301= | Silent (SNP) | VAF 178/428 reads (42%) | catalogued as COSV100803372; called by muse, mutect2, varscan2
- TINAG | c.1413G>A p.T471= | Silent (SNP) | VAF 177/436 reads (41%) | catalogued as rs746091391, COSV52507294; called by muse, mutect2, varscan2
- TMEM132C | c.2214C>T p.T738= | Silent (SNP) | VAF 151/470 reads (32%) | called by muse, mutect2, varscan2
- TNXB | c.11595C>T p.T3865= (on ENST00000647633; = p.T3618= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 162/1274 reads (13%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.228G>A p.K76= | Silent (SNP) | VAF 204/595 reads (34%) | called by muse, mutect2, varscan2
- TPPP2 | c.252G>A p.G84= | Silent (SNP) | VAF 166/423 reads (39%) | catalogued as COSV58795687; called by muse, mutect2, varscan2
- TRIOBP | c.591C>T p.S197= | Silent (SNP) | VAF 199/518 reads (38%) | called by muse, mutect2, varscan2
- TRPM3 | c.5004G>A p.R1668= (on ENST00000357533 / NM_001366142.2; = p.R1523= on NM_020952.6) | Silent (SNP) | VAF 89/281 reads (32%) | called by muse, mutect2, varscan2
- TSHZ3 | c.234C>A p.I78= | Silent (SNP) | VAF 182/438 reads (42%) | called by mutect2, varscan2
- TTC29 | c.477G>A p.R159= | Silent (SNP) | VAF 281/654 reads (43%) | catalogued as COSV57279485; called by muse, mutect2, varscan2
- TTN | c.10683C>T p.I3561= (on ENST00000591111; = p.I3515= on NM_003319.4) | Silent (SNP) | VAF 190/465 reads (41%) | called by muse, mutect2, varscan2
- UBQLN3 | c.600G>A p.L200= | Silent (SNP) | VAF 207/527 reads (39%) | catalogued as COSV61165778; called by muse, mutect2, varscan2
- UGT3A1 | c.189G>A p.L63= | Silent (SNP) | VAF 153/391 reads (39%) | called by muse, mutect2, varscan2
- USH1C | c.142C>T p.L48= | Silent (SNP) | VAF 215/600 reads (36%) | catalogued as COSV99142087; called by muse, mutect2, varscan2
- USH2A | c.7848T>G p.T2616= | Silent (SNP) | VAF 287/627 reads (46%) | catalogued as rs184886846; called by muse, mutect2, varscan2
- USP18 | c.183A>C p.G61= | Silent (SNP) | VAF 178/457 reads (39%) | called by muse, mutect2, varscan2
- USP40 | c.1704C>T p.L568= | Silent (SNP) | VAF 154/421 reads (37%) | catalogued as rs1369924519, COSV52480263; called by muse, mutect2, varscan2
- VAPB | c.63C>T p.P21= | Silent (SNP) | VAF 226/435 reads (52%) | catalogued as rs1211879173, COSV55666904; called by muse, mutect2, varscan2
- VPS13B | c.3685C>T p.L1229= | Silent (SNP) | VAF 391/610 reads (64%) | called by muse, mutect2, varscan2
- VSX1 | c.201G>A p.G67= | Silent (SNP) | VAF 168/331 reads (51%) | called by muse, mutect2, varscan2
- VWCE | c.1260G>A p.R420= | Silent (SNP) | VAF 137/371 reads (37%) | called by muse, mutect2, varscan2
- WDR48 | c.1701C>T p.F567= | Silent (SNP) | VAF 128/403 reads (32%) | called by muse, mutect2, varscan2
- ZAN | c.841C>T p.L281= | Silent (SNP) | VAF 500/838 reads (60%) | called by muse, mutect2, varscan2
- ZNF367 | c.363C>T p.A121= | Silent (SNP) | VAF 15/305 reads (5%) | called by muse, mutect2
- ZNF404 | c.918G>A p.K306= | Silent (SNP) | VAF 148/382 reads (39%) | catalogued as COSV100182525; called by muse, mutect2, varscan2
- ZNF444 | c.699C>T p.P233= | Silent (SNP) | VAF 177/484 reads (37%) | catalogued as rs760947107, COSV61363362; called by muse, mutect2, varscan2
- ZNF711 | c.648G>A p.E216= | Silent (SNP) | VAF 75/99 reads (76%) | called by muse, mutect2, varscan2
- ZNF727 | c.315C>T p.S105= | Silent (SNP) | VAF 263/948 reads (28%) | called by muse, mutect2, varscan2
- ZNF862 | c.1362G>A p.R454= | Silent (SNP) | VAF 131/424 reads (31%) | called by muse, mutect2, varscan2
- ZSCAN5A | c.135G>A p.V45= | Silent (SNP) | VAF 255/632 reads (40%) | called by muse, mutect2, varscan2
- AC092118.1 | n.87G>A | RNA (SNP) | VAF 147/380 reads (39%) | called by muse, mutect2, varscan2
- AC235097.1 | n.103G>A | RNA (SNP) | VAF 331/423 reads (78%) | called by muse, mutect2, varscan2
- ACSM5 | c.1436+27C>T | Intron (SNP) | VAF 112/205 reads (55%) | catalogued as rs1238556149; called by muse, mutect2, varscan2
- ADA2 | c.753+3988G>A | Intron (SNP) | VAF 163/452 reads (36%) | catalogued as rs562613700, COSV52832076; called by muse, mutect2, varscan2
- AGPAT1 | c.*8C>T | 3'UTR (SNP) | VAF 110/420 reads (26%) | called by muse, mutect2, varscan2
- AL662899.2 | c.367+268C>T | Intron (SNP) | VAF 254/942 reads (27%) | catalogued as rs1562052801; called by muse, mutect2, varscan2
- AOX1 | c.1060-37G>A | Intron (SNP) | VAF 45/144 reads (31%) | called by muse, mutect2, varscan2
- AP001172.2 | chr21:16422825 G>A | 5'Flank (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620196 G>A | 3'Flank (SNP) | VAF 62/157 reads (39%) | catalogued as rs1266227473; called by muse, mutect2, varscan2
- ATF2 | c.1291+14C>T | Intron (SNP) | VAF 120/312 reads (38%) | called by muse, mutect2, varscan2
- BBOF1 | c.792+35C>T | Intron (SNP) | VAF 66/106 reads (62%) | called by muse, mutect2, varscan2
- BMP1 | c.1298-61C>T | Intron (SNP) | VAF 71/304 reads (23%) | called by muse, mutect2, varscan2
- BTN3A1 | c.1018+53C>T | Intron (SNP) | VAF 127/438 reads (29%) | catalogued as rs547099840; called by muse, mutect2
- C5orf67 | n.388G>A | RNA (SNP) | VAF 92/313 reads (29%) | catalogued as rs1201473349; called by muse, mutect2, varscan2
- C5orf67 | n.387G>A | RNA (SNP) | VAF 91/309 reads (29%) | called by muse, mutect2, varscan2
- C7orf66 | n.285G>A | RNA (SNP) | VAF 429/748 reads (57%) | called by muse, mutect2, varscan2
- C9orf106 | n.43G>A | RNA (SNP) | VAF 62/126 reads (49%) | called by muse, mutect2, varscan2
- CACNA1D | c.623+22G>A | Intron (SNP) | VAF 80/190 reads (42%) | called by muse, mutect2, varscan2
- CAPN8 | c.1833+9C>T | Intron (SNP) | VAF 201/438 reads (46%) | called by muse, mutect2, varscan2
- CCDC57 | c.2241+40C>T | Intron (SNP) | VAF 186/543 reads (34%) | called by muse, mutect2, varscan2
- CD300LG | c.885+368C>T | Intron (SNP) | VAF 168/426 reads (39%) | called by muse, mutect2, varscan2
- CD40 | c.559+99G>A | Intron (SNP) | VAF 106/194 reads (55%) | called by muse, mutect2, varscan2
- CDC123 | c.146+87C>T | Intron (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- CDC37 | chr19:10403566 C>T | 5'Flank (SNP) | VAF 13/23 reads (57%) | catalogued as rs1334515032; called by muse, mutect2, varscan2
- CLIC2 | c.*23G>A | 3'UTR (SNP) | VAF 83/98 reads (85%) | called by muse, mutect2, varscan2
- CSTA | c.*53C>T | 3'UTR (SNP) | VAF 58/150 reads (39%) | called by muse, varscan2
- CXCL12 | c.266+853C>T | Intron (SNP) | VAF 200/494 reads (40%) | called by muse, mutect2, varscan2
- CYP19A1 | c.744-53C>T | Intron (SNP) | VAF 45/115 reads (39%) | catalogued as rs1300481593; called by muse, mutect2, varscan2
- CYP4F12 | c.1314+61G>A | Intron (SNP) | VAF 127/318 reads (40%) | catalogued as rs867140706; called by muse, mutect2, varscan2
- DAPK2 | c.660-36C>T | Intron (SNP) | VAF 75/163 reads (46%) | called by muse, mutect2, varscan2
- DCAF13 | c.1251-36C>T | Intron (SNP) | VAF 39/188 reads (21%) | called by muse, mutect2, varscan2
- DDX27 | chr20:49219345 G>A | 5'Flank (SNP) | VAF 301/499 reads (60%) | catalogued as COSV100874635, COSV100874765; called by muse, mutect2, varscan2
- DENND4B | c.641-27G>A | Intron (SNP) | VAF 172/459 reads (37%) | called by muse, mutect2, varscan2
- DNAH17 | c.5745+33G>A | Intron (SNP) | VAF 99/229 reads (43%) | catalogued as rs774553012; called by muse, mutect2, varscan2
- DNAH7 | c.4336-30T>A | Intron (SNP) | VAF 38/90 reads (42%) | catalogued as COSV56758605; called by muse, mutect2, varscan2
- DTNBP1 | c.512-55A>G | Intron (SNP) | VAF 41/148 reads (28%) | called by muse, mutect2, varscan2
- EED | c.861-14C>T | Intron (SNP) | VAF 90/210 reads (43%) | catalogued as rs778176848; called by muse, mutect2, varscan2
- EEF1D | c.-7-2492C>T | Intron (SNP) | VAF 462/666 reads (69%) | called by muse, mutect2, varscan2
- EIF4E | c.-96C>T | 5'UTR (SNP) | VAF 27/75 reads (36%) | catalogued as rs924250134; called by muse, mutect2, varscan2
- EIF4E2 | c.*83C>T | 3'UTR (SNP) | VAF 46/139 reads (33%) | called by muse, mutect2, varscan2
- ELFN2 | c.*92G>A | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2
- EZHIP | c.-15G>A | 5'UTR (SNP) | VAF 149/201 reads (74%) | called by muse, mutect2, varscan2
- FGD2 | c.685-96C>T | Intron (SNP) | VAF 96/301 reads (32%) | catalogued as rs1226002750; called by muse, mutect2, varscan2
- FLNB | c.7418-56A>G | Intron (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- FOXP1 | c.*5C>T | 3'UTR (SNP) | VAF 156/373 reads (42%) | catalogued as rs918813752, COSV59545764; called by muse, mutect2, varscan2
- FRMD4B | c.502-16C>T | Intron (SNP) | VAF 98/269 reads (36%) | catalogued as rs375326290; called by muse, mutect2, varscan2
- FUS | c.800-48T>A | Intron (SNP) | VAF 122/291 reads (42%) | called by muse, mutect2, varscan2
- GAPDH | c.526-71C>T | Intron (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.2811+50C>T | Intron (SNP) | VAF 491/845 reads (58%) | called by muse, mutect2, varscan2
- HAAO | c.699+16G>A | Intron (SNP) | VAF 107/303 reads (35%) | called by muse, mutect2, varscan2
- HAVCR2 | c.59-12C>T | Intron (SNP) | VAF 186/500 reads (37%) | called by muse, mutect2, varscan2
- HLA-C | c.343+16C>T | Intron (SNP) | VAF 138/486 reads (28%) | catalogued as rs1459310647; called by muse, mutect2
- IQSEC3 | c.3114+203C>T | Intron (SNP) | VAF 81/204 reads (40%) | catalogued as rs782797649; called by muse, mutect2, varscan2
- IRAG2 | c.3799-74G>A | Intron (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- IRF8 | c.*42C>T | 3'UTR (SNP) | VAF 76/201 reads (38%) | catalogued as rs368437615; called by muse, mutect2, varscan2
- KCNK16 | c.802+87C>T | Intron (SNP) | VAF 219/789 reads (28%) | called by muse, mutect2, varscan2
- KDM6B | c.4909-38C>T | Intron (SNP) | VAF 153/385 reads (40%) | called by muse, mutect2, varscan2
- KRTAP12-4 | c.-11C>T | 5'UTR (SNP) | VAF 108/351 reads (31%) | called by muse, mutect2, varscan2
- KRTAP12-4 | c.-12C>T | 5'UTR (SNP) | VAF 105/345 reads (30%) | called by muse, mutect2, varscan2
- LAMP5 | c.*37C>T | 3'UTR (SNP) | VAF 265/432 reads (61%) | catalogued as rs750835618; called by muse, mutect2, varscan2
- LEUTX | chr19:39786191 C>T | 3'Flank (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- LINC01517 | n.181G>A | RNA (SNP) | VAF 62/158 reads (39%) | catalogued as rs879082887; called by muse, mutect2, varscan2
- MAP2K4 | c.814-13C>T | Intron (SNP) | VAF 153/381 reads (40%) | catalogued as rs567979401; called by muse, mutect2, varscan2
- MAP3K20 | c.987+4043C>T | Intron (SNP) | VAF 209/480 reads (44%) | called by muse, mutect2, varscan2
- MARCHF8 | c.423+38C>T | Intron (SNP) | VAF 60/141 reads (43%) | called by muse, mutect2, varscan2
- MED31 | chr17:6641000 G>A | 3'Flank (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- MINDY4 | c.663+56G>A | Intron (SNP) | VAF 55/125 reads (44%) | catalogued as rs1271862838; called by muse, mutect2, varscan2
- MKLN1 | c.2086+61G>A | Intron (SNP) | VAF 119/392 reads (30%) | catalogued as rs766303554; called by muse, mutect2, varscan2
- MSL1 | c.*95T>C | 3'UTR (SNP) | VAF 45/109 reads (41%) | called by muse, mutect2, varscan2
- MSLNL | c.503+50C>T | Intron (SNP) | VAF 58/157 reads (37%) | catalogued as rs761532587; called by muse, mutect2, varscan2
- MTBP | c.-29C>T | 5'UTR (SNP) | VAF 143/702 reads (20%) | called by muse, mutect2, varscan2
- MUC19 | n.12055G>A | RNA (SNP) | VAF 140/588 reads (24%) | catalogued as rs1289304193; called by muse, mutect2
- MUC20 | c.*66C>T | 3'UTR (SNP) | VAF 94/226 reads (42%) | called by muse, mutect2, varscan2
- MYOCD | c.2187+26G>A | Intron (SNP) | VAF 88/229 reads (38%) | called by muse, mutect2, varscan2
- MYOF | c.*16C>T | 3'UTR (SNP) | VAF 179/257 reads (70%) | catalogued as rs1014068736, COSV100825681; called by muse, mutect2, varscan2
- MYRF | c.135-35C>T | Intron (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- NAP1L4 | c.607-56C>T | Intron (SNP) | VAF 46/124 reads (37%) | called by muse, mutect2, varscan2
- NFS1 | c.-59C>T | 5'UTR (SNP) | VAF 106/376 reads (28%) | called by muse, mutect2, varscan2
- NIPBL | c.3122-52C>T | Intron (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- OLIG3 | c.-55C>T | 5'UTR (SNP) | VAF 95/130 reads (73%) | called by muse, mutect2, varscan2
- OR1D2 | chr17:3091964 C>T | 3'Flank (SNP) | VAF 13/45 reads (29%) | catalogued as rs1039604719; called by muse, mutect2, varscan2
- OR1D2 | chr17:3091965 C>T | 3'Flank (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- OXA1L | c.849+32C>T | Intron (SNP) | VAF 122/324 reads (38%) | called by muse, mutect2, varscan2
- PACRGL | c.*56+4711C>T | Intron (SNP) | VAF 72/174 reads (41%) | called by muse, mutect2, varscan2
- PAK4 | c.*80C>T | 3'UTR (SNP) | VAF 46/119 reads (39%) | called by muse, mutect2, varscan2
- PCP4 | c.*4G>A | 3'UTR (SNP) | VAF 116/278 reads (42%) | called by muse, mutect2, varscan2
- PI4KA | c.4995+31C>T | Intron (SNP) | VAF 180/422 reads (43%) | catalogued as rs1168599971; called by muse, mutect2, varscan2
- PIN1 | c.59-21C>T | Intron (SNP) | VAF 116/263 reads (44%) | called by muse, mutect2, varscan2
- PITPNM1 | c.1484+54G>A | Intron (SNP) | VAF 160/337 reads (47%) | called by muse, mutect2, varscan2
- PKN1 | c.2216+44G>A | Intron (SNP) | VAF 116/247 reads (47%) | called by muse, mutect2, varscan2
- PLXNA2 | c.4287-94C>T | Intron (SNP) | VAF 95/207 reads (46%) | called by muse, mutect2, varscan2
- PPP1R16B | c.-95C>T | 5'UTR (SNP) | VAF 40/63 reads (63%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45227400 C>T | 3'Flank (SNP) | VAF 121/319 reads (38%) | called by muse, mutect2, varscan2
- PRKAG2 | c.684+42G>A | Intron (SNP) | VAF 239/367 reads (65%) | called by muse, mutect2, varscan2
- PROM2 | c.1115-93C>T | Intron (SNP) | VAF 73/161 reads (45%) | catalogued as COSV58300518; called by muse, mutect2, varscan2
- PRTFDC1 | c.405+4281G>A | Intron (SNP) | VAF 102/300 reads (34%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5285G>A | Intron (SNP) | VAF 151/463 reads (33%) | catalogued as rs112889033; called by muse, mutect2, varscan2
- RAB30 | c.361+58C>T | Intron (SNP) | VAF 88/207 reads (43%) | called by muse, mutect2, varscan2
- REG3A | c.76+56G>A | Intron (SNP) | VAF 111/265 reads (42%) | called by muse, mutect2, varscan2
- RGPD3 | c.-47G>A | 5'UTR (SNP) | VAF 62/136 reads (46%) | catalogued as rs1209797965, COSV58746784; called by muse, mutect2, varscan2
- RPEL1 | c.-97G>A | 5'UTR (SNP) | VAF 24/36 reads (67%) | called by muse, mutect2, varscan2
- RTF1 | c.-8G>A | 5'UTR (SNP) | VAF 88/219 reads (40%) | called by muse, mutect2, varscan2
- RTKN | chr2:74421642 G>A | 3'Flank (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- SAMD12 | c.193-49934G>A | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- SFXN1 | c.434+69C>T | Intron (SNP) | VAF 37/109 reads (34%) | catalogued as COSV58493386; called by muse, mutect2
- SH2D3C | c.515+2706G>A | Intron (SNP) | VAF 69/164 reads (42%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*40C>T | 3'UTR (SNP) | VAF 117/261 reads (45%) | called by muse, mutect2, varscan2
- SHKBP1 | chr19:40576864 G>A | 5'Flank (SNP) | VAF 25/42 reads (60%) | catalogued as rs1178381687; called by muse, mutect2, varscan2
- SIDT2 | c.1420-21C>T | Intron (SNP) | VAF 94/191 reads (49%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.422-45G>A | Intron (SNP) | VAF 95/232 reads (41%) | catalogued as rs767835816; called by muse, mutect2, varscan2
- SLC12A5 | c.121+14G>A | Intron (SNP) | VAF 233/399 reads (58%) | called by muse, mutect2, varscan2
- SLC9A3 | c.2252-83C>T | Intron (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- SLCO6A1 | c.-62C>T | 5'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- SP140 | c.1720+12A>C | Intron (SNP) | VAF 111/320 reads (35%) | called by muse, mutect2, varscan2
- SPEG | c.2882-1027C>T | Intron (SNP) | VAF 136/303 reads (45%) | called by muse, mutect2, varscan2
- SSPOP | n.11892C>T | RNA (SNP) | VAF 210/820 reads (26%) | catalogued as rs1403315196; called by muse, mutect2, varscan2
- SSUH2 | c.-19C>T | 5'UTR (SNP) | VAF 153/403 reads (38%) | catalogued as rs1176966672; called by muse, mutect2, varscan2
- TARM1 | c.*4C>T | 3'UTR (SNP) | VAF 122/323 reads (38%) | catalogued as rs1278926512, COSV71524786; called by muse, mutect2, varscan2
- TEDC2 | chr16:2460095 G>A | 5'Flank (SNP) | VAF 48/113 reads (42%) | catalogued as rs1190598082; called by muse, mutect2, varscan2
- TMEM63A | c.747-89C>T | Intron (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- TRIM66 | c.-60C>T | 5'UTR (SNP) | VAF 90/266 reads (34%) | called by muse, mutect2, varscan2
- TRIP10 | c.-70G>A | 5'UTR (SNP) | VAF 55/110 reads (50%) | called by muse, mutect2, varscan2
- UBE2L5 | c.*78C>T | 3'UTR (SNP) | VAF 87/135 reads (64%) | called by muse, mutect2, varscan2
- VN1R2 | c.-3G>A | 5'UTR (SNP) | VAF 50/151 reads (33%) | called by muse, mutect2
- VPREB3 | c.*62C>T | 3'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- VSTM2A | c.*39C>T | 3'UTR (SNP) | VAF 220/512 reads (43%) | called by muse, mutect2, varscan2
- WDR45B | c.-100C>T | 5'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- ZNF346 | c.-27C>T | 5'UTR (SNP) | VAF 115/285 reads (40%) | catalogued as rs1178349751; called by muse, mutect2, varscan2
- ZNF382 | c.*98C>T | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
